Somatic mutation profile of tumor specimen TCGA-21-1079-01A (aliquot TCGA-21-1079-01A-01W-0782-08) from TCGA case TCGA-21-1079, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.7 years (26,176 days).
Specimen TCGA-21-1079-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d15c403-66f2-4b69-b724-5def561b10ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1079-11A (Solid Tissue Normal), aliquot TCGA-21-1079-11A-01W-0782-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104e13cf-037d-426b-ad2b-eb9dc7f0c4e9

The open-access MAF lists 2,059 somatic variants for this specimen: 1,312 protein-altering or splice-affecting, 699 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,188, Silent 699, Nonsense Mutation 81, Splice Site 20, Intron 16, RNA 14, Splice Region 13, 3'UTR 8, Frame Shift Del 7, 5'Flank 7, 3'Flank 2, Frame Shift Ins 1.

Variants (750 of 2,059; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2A | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs926027867, COSV100804629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASR | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121909266, CM950200, COSV99949282; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 25/41 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- IL7R | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193922645, COSV100286475; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 169/233 reads (73%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- RAD51C | c.145+1G>A p.X49_splice | Splice Site (SNP) | VAF 41/113 reads (36%) | catalogued as rs757128712, CS102528, COSV53616245; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RHO | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527236103, CM952219, COSV99960721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 200/466 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 29/143 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs769626580, COSV99254986; called by muse, mutect2, varscan2
- AACS | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 145/322 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1458733031, COSV99908205; called by muse, mutect2, varscan2
- AADACL4 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100879476; called by muse, mutect2, varscan2
- AADAT | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100528685; called by muse, mutect2, varscan2
- AAR2 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100299383; called by muse, mutect2, varscan2
- ABCA4 | c.3832G>A p.E1278K | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64676168; called by muse, mutect2, varscan2
- ABCA4 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100933179; called by muse, mutect2, varscan2
- ABCA6 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99446867, COSV99447241; called by muse, mutect2, varscan2
- ABCA8 | c.2646G>A p.G882= | Splice Region (SNP) | VAF 46/131 reads (35%) | catalogued as COSV99286503; called by muse, mutect2, varscan2
- ABCA9 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.21); catalogued as COSV100383345; called by muse, mutect2, varscan2
- ABCB4 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55933378; called by muse, mutect2, varscan2
- ABCC11 | c.3782C>T p.S1261L | Missense Mutation (SNP) | VAF 254/636 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV100750994; called by muse, mutect2, varscan2
- ABCC11 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100750997; called by muse, mutect2, varscan2
- ABCC8 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56847974; called by muse, varscan2
- ABCC8 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56853650; called by muse, varscan2
- ABCC8 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1222549831, COSV100217571; called by muse, mutect2, varscan2
- ABL2 | c.1261C>T p.H421Y (on ENST00000502732 / NM_007314.4; = p.H406Y on NM_005158.5) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV100772897; called by muse, mutect2, varscan2
- ABLIM1 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV99522470; called by muse, mutect2, varscan2
- ABLIM1 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 148/598 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs768481591, COSV53303406; called by muse, mutect2, varscan2
- ABLIM3 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100448627; called by muse, mutect2, varscan2
- ACAN | c.4217G>A p.G1406E | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100718820; called by muse, varscan2
- ACAP1 | c.1982A>C p.K661T | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99341870; called by muse, mutect2, varscan2
- ACLY | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100709818; called by muse, mutect2, varscan2
- ACP2 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99921775; called by muse, mutect2, varscan2
- ACSBG1 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99357662; called by muse, mutect2, varscan2
- ACSL5 | c.542C>T p.A181V (on ENST00000354273; = p.A237V on NM_016234.3) | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV61132992; called by muse, mutect2, varscan2
- ACSL6 | c.1975C>T p.H659Y (on ENST00000379240; = p.H684Y on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV57298527; called by muse, mutect2, varscan2
- ACSM2B | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV61658676, COSV61659320; called by muse, mutect2, varscan2
- ACSS3 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54087351; called by muse, mutect2, varscan2
- ACTBL2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV101379390; called by muse, mutect2, varscan2
- ACTL9 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV100185479; called by muse, mutect2, varscan2
- ACVR1C | c.1037T>G p.V346G | Missense Mutation (SNP) | VAF 119/280 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99694919; called by muse, mutect2, varscan2
- ADAM11 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52346253, COSV52347047; called by muse, mutect2, varscan2
- ADAM2 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.192); catalogued as COSV99697687; called by muse, mutect2, varscan2
- ADAM22 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99717796; called by muse, mutect2, varscan2
- ADAM28 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV99739386; called by muse, mutect2, varscan2
- ADAM7 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 268/608 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150319320, COSV51535996; called by muse, mutect2, varscan2
- ADAM7 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51538725; called by muse, mutect2, varscan2
- ADAMTS2 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs200022037, COSV52365296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.2541C>G p.N847K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV52364795, COSV52366033, COSV99283334; called by muse, mutect2, varscan2
- ADAMTS2 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99202754; called by muse, mutect2, varscan2
- ADAMTS20 | c.4495T>C p.Y1499H | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.452); catalogued as COSV101239935; called by muse, mutect2, varscan2
- ADAMTS3 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1406586324, COSV99711720; called by muse, mutect2, varscan2
- ADAMTS4 | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 49/119 reads (41%) | catalogued as COSV100917837, COSV100917884; called by muse, mutect2, varscan2
- ADAMTS6 | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142650468; called by muse, mutect2, varscan2
- ADAMTS7 | c.2887C>T p.Q963* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs779766764, COSV101183199; called by muse, mutect2, varscan2
- ADCY10 | c.4573G>A p.G1525R | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100896997; called by muse, mutect2, varscan2
- ADCY10 | c.2750A>T p.E917V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100896998; called by muse, mutect2, varscan2
- ADCY8 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs751806556, COSV53920771; called by muse, varscan2
- ADCY8 | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.459); catalogued as COSV99653487; called by muse, varscan2
- ADGRB3 | c.4111G>T p.E1371* | Nonsense Mutation (SNP) | VAF 123/282 reads (44%) | catalogued as COSV53237027, COSV99486300; called by muse, mutect2, varscan2
- ADGRD1 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 115/202 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99896448; called by muse, mutect2, varscan2
- ADGRE3 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs373403949; called by muse, mutect2, varscan2
- ADGRV1 | c.14093C>T p.S4698F | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101316268; called by muse, mutect2, varscan2
- ADM | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV99534324; called by muse, mutect2, varscan2
- ADNP | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 137/241 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs756841614, COSV100823812; called by muse, mutect2, varscan2
- ADPRHL1 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733504; called by muse, mutect2, varscan2
- AFF2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 218/345 reads (63%) | SIFT tolerated (0.64); PolyPhen benign (0.129); catalogued as COSV100650753; called by muse, mutect2, varscan2
- AFG3L2 | c.1471C>A p.L491I | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1301237417, COSV99302080; called by muse, mutect2, varscan2
- AGBL2 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100101951; called by muse, mutect2, varscan2
- AHDC1 | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99899600; called by muse, mutect2, varscan2
- AIM2 | c.104T>A p.I35N | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV100931122; called by muse, mutect2, varscan2
- ALDH3A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99856001; called by muse, mutect2, varscan2
- ALG9 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 62/367 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV101211934; called by muse, mutect2, varscan2
- ALK | c.4535C>A p.T1512K | Missense Mutation (SNP) | VAF 170/425 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV101202479; called by muse, mutect2, varscan2
- ALKBH1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV99380711; called by muse, mutect2, varscan2
- ALKBH1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV99380712; called by muse, mutect2, varscan2
- ALMS1 | c.12119C>T p.S4040L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs763327026, COSV100043239; ClinVar: uncertain significance; called by mutect2, varscan2
- AMER3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs747090041, COSV58470317; called by muse, mutect2, varscan2
- AMIGO1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as COSV100881095; called by muse, mutect2, varscan2
- AMOTL2 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99998269; called by muse, mutect2, varscan2
- AMPH | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 198/433 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1032416581, COSV100342680, COSV100343083; called by muse, mutect2, varscan2
- ANK2 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1563367580, COSV100003151; called by muse, mutect2, varscan2
- ANK2 | c.10355C>T p.S3452F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52155578; called by muse, mutect2, varscan2
- ANK3 | c.6599T>A p.F2200Y | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV99781421; called by muse, mutect2, varscan2
- ANKDD1A | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 50/142 reads (35%) | catalogued as rs1464597468, COSV100132738; called by muse, mutect2, varscan2
- ANKRA2 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.868); catalogued as COSV99707086; called by muse, mutect2, varscan2
- ANKRD11 | c.3277G>A p.G1093R | Missense Mutation (SNP) | VAF 171/219 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99970183; called by muse, mutect2, varscan2
- ANKRD12 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs568044210, COSV50837292; called by muse, mutect2, varscan2
- ANKRD17 | c.6562C>T p.P2188S | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs769741144, COSV100429702; called by muse, varscan2
- ANKRD17 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 247/642 reads (38%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.025); catalogued as COSV100429704; called by muse, mutect2, varscan2
- ANKRD24 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53672778; called by muse, mutect2, varscan2
- ANKRD30A | c.3157G>A p.G1053R (on ENST00000611781; = p.G997R on NM_052997.2) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100654144, COSV100654257; called by muse, mutect2, varscan2
- ANKRD44 | c.2446C>A p.H816N | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV99985635; called by muse, mutect2, varscan2
- ANKRD55 | c.866T>C p.M289T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs767831535, COSV100591525; called by muse, mutect2, varscan2
- ANKRD6 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as COSV100330232; called by muse, mutect2, varscan2
- ANKRD6 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV100330234; called by muse, mutect2, varscan2
- ANO4 | c.1102G>A p.G368R (on ENST00000392977 / NM_001286615.2; = p.G333R on NM_178826.4) | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153445; called by muse, mutect2, varscan2
- ANO4 | c.1874A>G p.Y625C (on ENST00000392977 / NM_001286615.2; = p.Y590C on NM_178826.4) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs748862613, COSV100153446, COSV54600154; called by muse, mutect2, varscan2
- ANXA6 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905512; called by muse, mutect2, varscan2
- AOX1 | c.3006G>A p.W1002* | Nonsense Mutation (SNP) | VAF 182/381 reads (48%) | catalogued as COSV101022169; called by muse, mutect2, varscan2
- AP002512.3 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54408602; called by muse, mutect2, varscan2
- AP4M1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100385074; called by muse, mutect2, varscan2
- APOA4 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV63361214; called by muse, mutect2, varscan2
- APOF | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs768544293, COSV100029063; called by muse, mutect2, varscan2
- AQP10 | c.233-1G>A p.X78_splice | Splice Site (SNP) | VAF 27/55 reads (49%) | catalogued as rs368035822; called by muse, mutect2, varscan2
- ARHGAP21 | c.4933C>T p.P1645S | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.149); catalogued as rs763923481, COSV100256499; called by muse, mutect2, varscan2
- ARHGAP26 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV99191252; called by muse, varscan2
- ARHGAP26 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99191255; called by muse, varscan2
- ARMC4 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV99518883; called by muse, mutect2, varscan2
- ARMC8 | c.658C>T p.P220S (on ENST00000469044 / NM_001363941.2; = p.P206S on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as COSV100627793; called by muse, mutect2, varscan2
- ARMCX5 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 171/221 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV99863470; called by muse, mutect2, varscan2
- ARMH4 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 129/307 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1441212152, COSV99958686; called by muse, mutect2, varscan2
- ARMH4 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as COSV99958690; called by muse, mutect2, varscan2
- ARPP21 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 83/124 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV99492733; called by muse, mutect2, varscan2
- ART3 | c.1103T>G p.L368R (on ENST00000355810 / NM_001377173.1; = p.L357R on NM_001179.6) | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV99345409; called by muse, mutect2, varscan2
- ASB3 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV99712319; called by muse, mutect2, varscan2
- ASB3 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99712323; called by muse, mutect2, varscan2
- ASIC1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 94/394 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759280738, COSV57317834; called by muse, mutect2, varscan2
- ATG4D | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV100521083; called by muse, mutect2, varscan2
- ATM | c.689A>T p.N230I | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as CD031819, COSV99590900; called by muse, mutect2, varscan2
- ATOH1 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.366); catalogued as rs1250650094, COSV60039078; called by muse, mutect2, varscan2
- ATP10A | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.086); catalogued as rs573005947, COSV100791406; called by muse, mutect2, varscan2
- ATP10B | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 83/349 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV100469609; called by muse, mutect2, varscan2
- ATP13A1 | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV99366438; called by muse, mutect2, varscan2
- ATP13A2 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 90/220 reads (41%) | catalogued as COSV100454301, COSV58701510; called by muse, mutect2, varscan2
- ATP2B1 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV99665964; called by muse, mutect2, varscan2
- ATP6V0B | c.544T>A p.F182I | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99356570; called by muse, mutect2, varscan2
- ATP7B | c.4062G>A p.M1354I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99666765, COSV99666933; called by muse, mutect2, varscan2
- ATP8A2 | c.3559A>T p.K1187* | Nonsense Mutation (SNP) | VAF 36/113 reads (32%) | catalogued as COSV99683342; called by muse, mutect2, varscan2
- ATP9A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756587295, COSV58762895, COSV58762969; called by muse, mutect2, varscan2
- ATXN2L | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs999284888, COSV100294869; called by muse, mutect2, varscan2
- AVPR1B | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100899416; called by muse, mutect2, varscan2
- BAG6 | c.2267C>T p.S756F (on ENST00000676571; = p.S709F on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52994719; called by muse, mutect2, varscan2
- BARX2 | c.581A>T p.K194I | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99858918; called by muse, mutect2
- BCAN | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV100228324; called by muse, mutect2, varscan2
- BCAS3 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 118/255 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as rs776214324, COSV101176582; called by muse, mutect2, varscan2
- BCDIN3D | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.344); catalogued as rs1449770852, COSV100445557; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3840del p.F1280Lfs*7 | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | catalogued as rs765932206; called by mutect2, pindel, varscan2
- BLM | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 64/185 reads (35%) | catalogued as COSV100757282; called by muse, mutect2, varscan2
- BLM | c.2462T>C p.F821S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100757283; called by muse, mutect2, varscan2
- BMP3 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV99261903; called by muse, varscan2
- BNIP5 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs1483522599, COSV71325475; called by muse, mutect2, varscan2
- BRCA1 | c.4952C>T p.S1651F | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs80356938, COSV100524772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD8 | c.1315G>C p.V439L (on ENST00000254900 / NM_139199.2; = p.V512L on NM_006696.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99137322; called by muse, mutect2, varscan2
- BRWD1 | c.6881A>T p.E2294V | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV100313785; called by muse, mutect2, varscan2
- BSG | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1445031900, COSV61078035; called by mutect2, varscan2
- BSN | c.11704G>A p.G3902S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99609301; called by muse, mutect2, varscan2
- BTG4 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs140812937; called by muse, varscan2
- C10orf120 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776437508, COSV100271717; called by muse, mutect2, varscan2
- C10orf90 | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 207/518 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as COSV99504720; called by muse, mutect2
- C11orf53 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 154/320 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs750838550, COSV99724853; called by muse, mutect2, varscan2
- C1QB | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100152803; called by muse, mutect2, varscan2
- C1QTNF6 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.343); catalogued as rs1429565756, COSV99742329; called by muse, mutect2, varscan2
- C2orf16 | c.2537G>A p.W846* | Nonsense Mutation (SNP) | VAF 51/137 reads (37%) | catalogued as COSV100820904; called by muse, mutect2, varscan2
- C3orf33 | c.194C>T p.S65F (on ENST00000340171 / NM_001308229.2; = p.S22F on NM_173657.2) | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV60898655; called by muse, mutect2, varscan2
- CAB39 | c.693+1G>A p.X231_splice | Splice Site (SNP) | VAF 30/177 reads (17%) | catalogued as COSV99300017; called by muse, mutect2, varscan2
- CACNA1A | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64192027; called by muse, mutect2, varscan2
- CACNA1A | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64197989; called by muse, mutect2, varscan2
- CACNA1S | c.3878C>T p.A1293V | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100755209; called by muse, mutect2, varscan2
- CACNA1S | c.3754G>A p.G1252R | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs768780512, COSV100755210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs757788424, COSV100755211; called by muse, varscan2
- CACNB2 | c.1419C>A p.N473K (on ENST00000324631 / NM_201596.3; = p.N418K on NM_000724.4) | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV99995702; called by muse, mutect2, varscan2
- CACNB4 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52398964, COSV99138937; called by muse, mutect2, varscan2
- CAPG | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.194); catalogued as COSV99809523; called by muse, mutect2, varscan2
- CAPRIN2 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as COSV99195573; called by muse, mutect2, varscan2
- CARD10 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV99325221; called by muse, mutect2, varscan2
- CARMIL3 | c.3754G>T p.E1252* | Nonsense Mutation (SNP) | VAF 38/75 reads (51%) | catalogued as COSV99393623; called by muse, mutect2, varscan2
- CATSPER1 | c.2067G>A p.R689= | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56413124; called by muse, mutect2, varscan2
- CATSPER1 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56413574; called by muse, mutect2, varscan2
- CCDC110 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100294092; called by muse, mutect2, varscan2
- CCDC136 | c.2697A>T p.E899D | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99922955; called by muse, mutect2, varscan2
- CCDC141 | c.3365A>G p.D1122G | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99837197; called by muse, mutect2, varscan2
- CCDC146 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592958; called by muse, mutect2, varscan2
- CCDC180 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as COSV100827142; called by muse, mutect2, varscan2
- CCDC198 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99371341; called by muse, mutect2, varscan2
- CCDC57 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100492609; called by muse, mutect2
- CCDC74B | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as rs1463765108, COSV100134613; called by muse, mutect2, varscan2
- CCDC77 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1303140737, COSV99519993; called by muse, mutect2, varscan2
- CCT8L2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs753169200, COSV63461948, COSV63462013; called by muse, mutect2, varscan2
- CD163 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 68/459 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs71445158, COSV100776019; called by muse, mutect2, varscan2
- CD163L1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100550461; called by muse, mutect2
- CD4 | c.1009A>T p.K337* | Nonsense Mutation (SNP) | VAF 70/344 reads (20%) | catalogued as COSV99163849; called by muse, varscan2
- CD93 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs751105411, COSV99849421; called by muse, mutect2, varscan2
- CDAN1 | c.744A>C p.Q248H | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV99142176; called by muse, mutect2, varscan2
- CDC123 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as COSV99827095; called by muse, mutect2, varscan2
- CDH17 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV99217775; called by muse, mutect2, varscan2
- CDH22 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 75/121 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100952947; called by muse, mutect2, varscan2
- CDH23 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.074); catalogued as COSV99822752; called by muse, mutect2, varscan2
- CDH6 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 157/298 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV99420168, COSV99420502; called by muse, varscan2
- CDH6 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 137/249 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV54073077, COSV99420176; called by muse, mutect2, varscan2
- CDH9 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 116/208 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50258336; called by muse, mutect2, varscan2
- CDHR1 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.163); catalogued as COSV100259242; called by muse, mutect2, varscan2
- CDON | c.2932C>T p.L978F | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV99701769; called by muse, mutect2, varscan2
- CELSR3 | c.2546C>A p.T849K | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99374400; called by muse, mutect2, varscan2
- CENPC | c.2089G>A p.G697R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99894255; called by muse, mutect2, varscan2
- CENPL | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV61891671; called by muse, varscan2
- CENPT | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs368958219; called by muse, mutect2, varscan2
- CENPT | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99535270; called by muse, mutect2, varscan2
- CEP104 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764238062, COSV65512538; called by muse, mutect2, varscan2
- CEP250 | c.3631C>T p.P1211S | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV100699083; called by muse, mutect2, varscan2
- CEP55 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV65184958; called by muse, mutect2, varscan2
- CEP63 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 182/337 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.321); catalogued as COSV100132991; called by muse, mutect2, varscan2
- CES5A | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1170954689, COSV51866330; called by muse, mutect2, varscan2
- CFAP100 | c.832A>T p.K278* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100729340; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 120/150 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CFAP47 | c.2818G>T p.A940S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV52883872, COSV52892724, COSV99935401; called by muse, mutect2, varscan2
- CFAP65 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100445596; called by muse, mutect2, varscan2
- CHD1 | c.582A>T p.Q194H | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.423); catalogued as COSV99399704; called by muse, mutect2, varscan2
- CHD9 | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV99529499; called by muse, mutect2, varscan2
- CHGB | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV100973025; called by muse, mutect2, varscan2
- CHRM1 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 117/434 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.559); catalogued as COSV61008041; called by muse, mutect2, varscan2
- CHRNA9 | c.706A>T p.R236W | Missense Mutation (SNP) | VAF 1087/1714 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100039043; called by muse, varscan2
- CHRNB4 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV99929496; called by muse, mutect2, varscan2
- CHSY3 | c.1157A>C p.K386T | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV100519665; called by muse, mutect2, varscan2
- CILP | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99973749; called by muse, mutect2, varscan2
- CKAP5 | c.3944G>A p.R1315Q | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.143); catalogued as rs370734058; called by muse, mutect2, varscan2
- CLCN1 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100578321; called by muse, mutect2, varscan2
- CLCN6 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV100412097; called by muse, mutect2, varscan2
- CLCN7 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV99247525; called by muse, mutect2, varscan2
- CLEC10A | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54701377; called by muse, mutect2, varscan2
- CLEC4M | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs1239341492, COSV50221542; called by muse, mutect2, varscan2
- CLIC5 | c.1006G>A p.D336N (on ENST00000185206 / NM_001370649.1; = p.D177N on NM_016929.5) | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV51763504; called by muse, mutect2, varscan2
- CLIP3 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as rs868246258, COSV62113484; called by muse, mutect2, varscan2
- CLPSL2 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); catalogued as COSV100846316; called by muse, mutect2, varscan2
- CLSTN2 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV101515849; called by muse, mutect2, varscan2
- CLTA | c.712C>T p.L238F (on ENST00000242285 / NM_007096.4; = p.L208F on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/127 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99643720; called by muse, mutect2, varscan2
- CLUH | c.1369C>T p.R457C (on ENST00000435359; = p.R495C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs756743030, COSV101425739, COSV101425830; called by muse, mutect2, varscan2
- CMTR2 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 239/336 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100579276; called by muse, mutect2, varscan2
- CMYA5 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV71404933; called by muse, mutect2, varscan2
- CMYA5 | c.4114G>T p.E1372* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as COSV101484239; called by muse, mutect2, varscan2
- CMYA5 | c.6847G>A p.E2283K | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV101484240; called by muse, mutect2, varscan2
- CNDP1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750904832, COSV62593178, COSV62594471; called by muse, mutect2, varscan2
- CNKSR1 | c.1642C>T p.H548Y (on ENST00000374253 / NM_001297647.2; = p.H541Y on NM_006314.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.361); catalogued as COSV100128458; called by mutect2, varscan2
- CNTD1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1334467220, COSV100162161; called by muse, mutect2, varscan2
- CNTN1 | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100751730; called by muse, mutect2, varscan2
- CNTNAP4 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs375548298; called by muse, mutect2, varscan2
- CNTRL | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 78/126 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99443209; called by muse, mutect2, varscan2
- CNTROB | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66609545; called by muse, mutect2, varscan2
- COG3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246681532, COSV100596680; called by muse, mutect2, varscan2
- COL15A1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 125/159 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV66648533; called by muse, mutect2, varscan2
- COL1A2 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745363291, COSV51967649, COSV99798007; called by muse, mutect2, varscan2
- COL22A1 | c.2977G>A p.G993R | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279752; called by muse, varscan2
- COL22A1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100279753; called by muse, mutect2, varscan2
- COL22A1 | c.92-1G>T p.X31_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as rs1324431068, COSV100279756; called by muse, varscan2
- COL24A1 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs199669304, COSV65308657; called by muse, mutect2, varscan2
- COL3A1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483492; called by muse, mutect2, varscan2
- COL3A1 | c.4307C>T p.A1436V | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV100483494; called by muse, mutect2, varscan2
- COL4A1 | c.4712C>T p.P1571L | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775544336, COSV101011384; called by muse, mutect2, varscan2
- COL4A3 | c.4220A>G p.E1407G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.197); catalogued as COSV101170464; called by muse, varscan2
- COL4A4 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100307398; called by muse, mutect2, varscan2
- COL6A3 | c.7235G>A p.G2412E | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776496050, COSV55100623; called by muse, mutect2, varscan2
- COL6A6 | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV100650657; called by muse, mutect2, varscan2
- COL9A3 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100673520; called by muse, mutect2, varscan2
- COLEC10 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 176/326 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1443295985, COSV60520713; called by muse, mutect2, varscan2
- COLGALT2 | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 37/187 reads (20%) | catalogued as COSV100730806; called by muse, mutect2, varscan2
- COQ6 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 80/166 reads (48%) | catalogued as COSV99474084; called by muse, mutect2, varscan2
- CORIN | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs866964180, COSV99904127; called by muse, mutect2, varscan2
- CPA2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV55979697; called by muse, mutect2, varscan2
- CPA2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1055287172, COSV99744189; called by muse, mutect2, varscan2
- CPN2 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100103213; called by muse, mutect2, varscan2
- CPS1 | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 133/751 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750670270, CM114382, CM114383, COSV51802822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACD | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 106/200 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs371038521, COSV51719680; called by muse, mutect2, varscan2
- CRNN | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 188/500 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55120746; called by muse, varscan2
- CRTAC1 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234751891, COSV100085625; called by muse, mutect2, varscan2
- CSF3R | c.1071G>A p.K357= | Splice Region (SNP) | VAF 52/103 reads (50%) | catalogued as rs1329984526, COSV100118069; called by muse, mutect2, varscan2
- CSMD1 | c.9379G>A p.G3127S (on ENST00000520002; = p.G3126S on NM_033225.6) | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59289246, COSV59380853; called by muse, mutect2, varscan2
- CSMD1 | c.5551G>A p.E1851K (on ENST00000520002; = p.E1850K on NM_033225.6) | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59286044; called by muse, mutect2, varscan2
- CSMD1 | c.3223G>A p.G1075R (on ENST00000520002; = p.G1074R on NM_033225.6) | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151719; called by muse, mutect2, varscan2
- CSMD1 | c.2902G>A p.G968R (on ENST00000520002; = p.G967R on NM_033225.6) | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151722; called by muse, mutect2, varscan2
- CSMD3 | c.9034A>T p.T3012S (on ENST00000297405 / NM_001363185.1; = p.T2843S on NM_052900.3) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52283090, COSV99842291; called by muse, mutect2, varscan2
- CSMD3 | c.7582C>T p.L2528F (on ENST00000297405 / NM_001363185.1; = p.L2424F on NM_052900.3) | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52110220; called by muse, mutect2, varscan2
- CSMD3 | c.5551C>T p.R1851* (on ENST00000297405 / NM_001363185.1; = p.R1747* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 151/362 reads (42%) | catalogued as rs1221208540, COSV52173428; called by muse, mutect2, varscan2
- CSMD3 | c.4520C>T p.T1507M (on ENST00000297405 / NM_001363185.1; = p.T1403M on NM_052900.3) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs773527015, COSV99835209, COSV99840410, COSV99842296; called by muse, mutect2, varscan2
- CSMD3 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 190/420 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.067); catalogued as COSV99842297; called by muse, mutect2, varscan2
- CSN2 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1301037582, COSV61991715, COSV61992734; called by muse, mutect2, varscan2
- CSPP1 | c.2171C>T p.S724F (on ENST00000676605; = p.S683F on NM_024790.6) | Missense Mutation (SNP) | VAF 82/490 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV99139301; called by muse, mutect2, varscan2
- CSRP2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100222794; called by muse, mutect2, varscan2
- CST2 | c.231C>T p.I77= | Splice Region (SNP) | VAF 43/206 reads (21%) | catalogued as rs754596464, COSV59030523; called by muse, varscan2
- CTNND1 | c.2895G>A p.M965I (on ENST00000399050 / NM_001085458.2; = p.M938I on NM_001331.3) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV100650213; called by muse, mutect2, varscan2
- CUBN | c.10767C>A p.D3589E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.109); catalogued as COSV100913202; called by muse, mutect2, varscan2
- CUBN | c.2227G>A p.G743R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs868260579, COSV100913203; called by muse, mutect2, varscan2
- CUX2 | c.26T>A p.F9Y | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV99920318; called by muse, mutect2, varscan2
- CUX2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs752126465, COSV99920322; called by muse, mutect2, varscan2
- CXorf21 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV100973338; called by muse, mutect2, varscan2
- CYFIP2 | c.2899G>A p.G967R (on ENST00000616178 / NM_001291722.2; = p.G942R on NM_014376.4) | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100557510, COSV59041602; called by muse, mutect2, varscan2
- CYP2A6 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV56535608, COSV56537216; called by muse, mutect2, varscan2
- CYP2A6 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV56536360; called by muse, mutect2, varscan2
- CYP2C19 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs770375701, COSV64907081; called by muse, mutect2, varscan2
- CYP2C9 | c.820-1G>A p.X274_splice | Splice Site (SNP) | VAF 43/241 reads (18%) | catalogued as COSV53251226; called by muse, mutect2, varscan2
- CYP3A43 | c.1267A>T p.N423Y (on ENST00000354829 / NM_057095.3; = p.N424Y on NM_022820.5) | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99733509; called by muse, mutect2, varscan2
- CYP4F8 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100358184, COSV57854287; called by muse, mutect2, varscan2
- DAND5 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57684253; called by muse, mutect2, varscan2
- DAPL1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100007384; called by muse, mutect2, varscan2
- DCHS1 | c.2198T>G p.F733C | Missense Mutation (SNP) | VAF 222/604 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100202379; called by muse, mutect2, varscan2
- DCLK3 | c.1334A>C p.E445A | Missense Mutation (SNP) | VAF 188/306 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV101374057; called by muse, mutect2, varscan2
- DCN | c.960A>T p.K320N | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99272500; called by muse, mutect2, varscan2
- DCP1A | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV99588119; called by muse, mutect2, varscan2
- DCT | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs761718082, COSV100986266; called by muse, mutect2, varscan2
- DDR2 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906759; called by muse, mutect2, varscan2
- DDX5 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as COSV99858161; called by muse, mutect2, varscan2
- DDX51 | c.967A>T p.K323* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100223140; called by mutect2, varscan2
- DDX53 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 96/139 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100029035, COSV60069618; called by muse, mutect2, varscan2
- DEK | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99789046; called by muse, mutect2, varscan2
- DENND2B | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV58202104; called by muse, mutect2, varscan2
- DENND4B | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV63407510; called by muse, mutect2, varscan2
- DHX37 | c.3329T>A p.V1110D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100439397; called by muse, mutect2, varscan2
- DISP3 | c.1933G>A p.G645R | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs200478139, COSV53830836; called by muse, mutect2, varscan2
- DLC1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.154); catalogued as rs1385530515, COSV99364568; called by muse, mutect2, varscan2
- DLC1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); catalogued as rs1343321465, COSV99364573; called by muse, mutect2, varscan2
- DLGAP2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101422464; called by muse, mutect2
- DLGAP3 | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 180/772 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV99333000; called by muse, varscan2
- DLK1 | c.253T>A p.C85S | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100375354; called by muse, mutect2, varscan2
- DLL4 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs202066588; called by muse, mutect2, varscan2
- DLX3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101460580, COSV71547576; called by muse, mutect2, varscan2
- DMP1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1325648907, COSV99218897; called by muse, mutect2, varscan2
- DNAH10 | c.1906G>A p.E636K (on ENST00000409039; = p.E575K on NM_207437.3) | Missense Mutation (SNP) | VAF 124/230 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.139); catalogued as COSV68997110; called by muse, mutect2, varscan2
- DNAH10 | c.5951C>T p.S1984F (on ENST00000409039; = p.S1923F on NM_207437.3) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV68999903; called by muse, mutect2, varscan2
- DNAH3 | c.10529G>A p.G3510E | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.151); catalogued as COSV99769371; called by muse, mutect2, varscan2
- DNAH8 | c.7203T>A p.D2401E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100546593; called by muse, mutect2, varscan2
- DNAI1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99647010; called by muse, mutect2, varscan2
- DNAJC17 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591808; called by muse, mutect2, varscan2
- DNM1L | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 28/49 reads (57%) | catalogued as COSV99846314; called by muse, mutect2, varscan2
- DNM2 | c.2531C>T p.P844L (on ENST00000355667 / NM_001005360.3; = p.P840L on NM_004945.3) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as rs1398139585, COSV99284238; ClinVar: uncertain significance; called by muse, mutect2
- DNMT3B | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99142755; called by muse, mutect2, varscan2
- DOCK2 | c.3697G>A p.D1233N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV99914235; called by muse, mutect2, varscan2
- DOCK4 | c.5666G>A p.G1889E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs750073763, COSV101447925, COSV70238343; called by muse, mutect2, varscan2
- DOCK5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs772869298, COSV52400213; called by muse, mutect2, varscan2
- DSEL | c.3076T>C p.F1026L | Missense Mutation (SNP) | VAF 128/185 reads (69%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.99); catalogued as COSV100025926; called by muse, mutect2, varscan2
- DSPP | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); catalogued as COSV99217732; called by muse, mutect2, varscan2
- DST | c.22000G>A p.G7334R (on ENST00000361203 / NM_001374722.1; = p.G5044R on NM_015548.5) | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.108); catalogued as COSV99758555; called by muse, mutect2, varscan2
- DUOX1 | c.2718G>C p.E906D | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV100368265; called by muse, mutect2, varscan2
- DVL2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs758359254, COSV50035801; called by muse, mutect2, varscan2
- DYNC1I1 | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV100268870; called by muse, mutect2, varscan2
- DYNC2H1 | c.9791C>T p.S3264F | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100519254; called by muse, mutect2, varscan2
- DYNLRB1 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV100307822; called by muse, mutect2, varscan2
- DYSF | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50664057, COSV99249453; called by muse, mutect2, varscan2
- EAF1 | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV101085072; called by muse, mutect2, varscan2
- ECRG4 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV53002024; called by muse, mutect2, varscan2
- ECSIT | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV99369169; called by muse, mutect2, varscan2
- EEA1 | c.3535G>A p.A1179T | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59290519; called by muse, mutect2, varscan2
- EFCAB13 | c.2668A>G p.M890V | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs745456225, COSV100516791; called by muse, mutect2, varscan2
- EGF | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 131/620 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1560698635, COSV99491234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHBP1L1 | c.2653G>A p.G885R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV100499960; called by muse, mutect2, varscan2
- EHBP1L1 | c.2654G>A p.G885E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100499961; called by muse, mutect2, varscan2
- EIF3D | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 200/686 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779180489, COSV53404231; called by muse, mutect2, varscan2
- ELAVL4 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 111/260 reads (43%) | catalogued as COSV100836841, COSV63917656; called by muse, mutect2, varscan2
- ELF1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1170554406, COSV99523248; called by muse, mutect2, varscan2
- ELN | c.1930G>A p.G644R (on ENST00000320399 / NM_001278939.1; = p.G611R on NM_000501.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as COSV99332921; called by muse, mutect2, varscan2
- ELOA2 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99797416; called by muse, mutect2, varscan2
- ENDOD1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV53591399; called by muse, mutect2, varscan2
- ENG | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100785329; called by muse, mutect2, varscan2
- EP400 | c.4435C>T p.P1479S | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100201860; called by muse, mutect2, varscan2
- EPB41L3 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100549857; called by muse, mutect2, varscan2
- EPG5 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957762; called by muse, varscan2
- EPHA3 | c.1148T>A p.L383H | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV100347243; called by muse, mutect2, varscan2
- EPHA5 | c.2433C>A p.N811K | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs774897926, COSV99900286; called by muse, mutect2, varscan2
- EPHB6 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100844378; called by muse, mutect2, varscan2
- ERICH6 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs1306703790, COSV99901855; called by muse, mutect2, varscan2
- ERN2 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV99892021; called by muse, mutect2, varscan2
- EVPL | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100044916; called by muse, mutect2, varscan2
- EXT2 | c.541G>A p.D181N (on ENST00000343631; = p.D214N on NM_000401.3) | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100640656, COSV59153877; called by muse, mutect2, varscan2
- EYA4 | c.1790G>A p.R597K (on ENST00000531901 / NM_001301013.1; = p.R591K on NM_004100.5) | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100766135; called by muse, mutect2, varscan2
- EYS | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV61003709; called by muse, mutect2, varscan2
- EYS | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as COSV100676912; called by muse, mutect2, varscan2
- EZH2 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100235902, COSV100236266; called by muse, mutect2, varscan2
- EZH2 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100236268; called by muse, mutect2, varscan2
- EZR | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100455041; called by muse, mutect2, varscan2
- F10 | c.1043G>T p.W348L | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as CM0910089, COSV100979273; called by muse, mutect2
- F13B | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 211/427 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100803370; called by muse, mutect2, varscan2
- F9 | c.1330T>C p.Y444H | Missense Mutation (SNP) | VAF 122/165 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM094079, COSV99496779; called by muse, mutect2, varscan2
- FAM107A | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.187); catalogued as COSV100723990; called by muse, mutect2, varscan2
- FAM124B | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54739102; called by muse, mutect2, varscan2
- FAM135A | c.335C>T p.S112F (on ENST00000370479 / NM_001351599.1; = p.S69F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.908); catalogued as COSV52054814; called by muse, mutect2, varscan2
- FAM135A | c.548C>A p.P183H (on ENST00000370479 / NM_001351599.1; = p.P140H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99526387; called by muse, mutect2, varscan2
- FAM153A | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 112/424 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV100647091; called by muse, mutect2, varscan2
- FAM217A | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51159160, COSV99212780; called by muse, mutect2, varscan2
- FAM83G | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100525382; called by muse, mutect2, varscan2
- FAM83G | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV100525383; called by muse, mutect2, varscan2
- FASTKD3 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 130/269 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52941547, COSV52945284; called by muse, mutect2, varscan2
- FAT3 | c.3523C>T p.P1175S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99968519; called by muse, mutect2, varscan2
- FAT4 | c.14492C>T p.P4831L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100627378, COSV100629463; called by muse, mutect2, varscan2
- FAT4 | c.14699C>T p.A4900V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100629465; called by muse, mutect2, varscan2
- FBLN1 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs755581581, COSV99411093; called by muse, mutect2, varscan2
- FBLN5 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs776279224, COSV50908787; called by muse, mutect2, varscan2
- FBN1 | c.4616G>A p.R1539Q | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs756882751, COSV57315279; called by muse, mutect2, varscan2
- FBN1 | c.2770G>A p.G924S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV100355970; called by muse, mutect2, varscan2
- FBN3 | c.7468T>G p.S2490A | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.076); catalogued as COSV99561490; called by muse, mutect2, varscan2
- FBXL7 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100310402, COSV61654403; called by muse, mutect2, varscan2
- FBXO2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs137861693; called by muse, mutect2, varscan2
- FBXO38 | c.3307T>G p.S1103A (on ENST00000340253 / NM_205836.3; = p.S1028A on NM_030793.5) | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99693765; called by muse, mutect2, varscan2
- FBXO40 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs1056199005, COSV100573258; called by muse, mutect2, varscan2
- FBXO42 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs1217707229, COSV100981872; called by muse, mutect2, varscan2
- FCGR1A | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs587648643, COSV64985795; called by mutect2, varscan2
- FCGR3B | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs756952234, COSV99670682; called by muse, mutect2, varscan2
- FCRL1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.538); catalogued as COSV63824810; called by muse, mutect2, varscan2
- FER1L6 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 147/1079 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV101206095; called by muse, mutect2, varscan2
- FES | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184747; called by muse, mutect2, varscan2
- FES | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs770223278, COSV99184748; called by muse, mutect2, varscan2
- FGF4 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99395427; called by muse, varscan2
- FIP1L1 | c.171-1G>A p.X57_splice | Splice Site (SNP) | VAF 31/143 reads (22%) | catalogued as COSV100184596; called by muse, mutect2, varscan2
- FLG | c.7118G>A p.G2373E | Missense Mutation (SNP) | VAF 132/479 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV100911898; called by muse, mutect2, varscan2
- FLG | c.6554G>A p.G2185E | Missense Mutation (SNP) | VAF 101/584 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs752353768, COSV64236017; called by muse, mutect2, varscan2
- FLG | c.5135G>A p.R1712Q | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.685); catalogued as rs763343831, COSV100911899, COSV64248489; called by muse, mutect2, varscan2
- FLNC | c.7165G>A p.D2389N | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV57969492; called by muse, mutect2, varscan2
- FLT1 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99164223; called by muse, mutect2, varscan2
- FLT1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56728855; called by muse, mutect2, varscan2
- FMO5 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1165757897, COSV99567291; called by muse, mutect2, varscan2
- FN1 | c.5278G>A p.E1760K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100117771; called by muse, mutect2, varscan2
- FNDC1 | c.2239G>A p.G747S | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV99796333; called by muse, mutect2, varscan2
- FNDC1 | c.2240G>A p.G747D | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99796335; called by muse, mutect2, varscan2
- FOLR1 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 73/218 reads (33%) | catalogued as COSV56617284; called by muse, mutect2, varscan2
- FOXH1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100023911; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1170G>A p.L390= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100437441; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201010209, COSV100437447; called by muse, mutect2, varscan2
- FREM1 | c.4160T>A p.I1387N | Missense Mutation (SNP) | VAF 68/106 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101085101; called by muse, mutect2, varscan2
- FRMD3 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 157/224 reads (70%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100418981; called by muse, mutect2, varscan2
- FRMPD3 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 223/308 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV99346816; called by muse, mutect2, varscan2
- FSCN3 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 235/557 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99133856; called by muse, mutect2, varscan2
- FSIP2 | c.17059G>A p.D5687N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100555814; called by muse, mutect2, varscan2
- FSIP2 | c.18361G>A p.V6121I | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.406); catalogued as rs1449943170, COSV100555816; called by muse, mutect2, varscan2
- FSTL5 | c.2423A>C p.Q808P | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs767400500, COSV100055482, COSV100058988; called by muse, mutect2, varscan2
- FSTL5 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60186077; called by muse, mutect2, varscan2
- FUT3 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.878); catalogued as COSV54607844; called by muse, mutect2
- FYN | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99992237; called by muse, mutect2, varscan2
- FZD2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100190697; called by muse, mutect2, varscan2
- FZD2 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV59528310; called by muse, mutect2, varscan2
- GABBR2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52294011, COSV99410958; called by muse, mutect2, varscan2
- GABRA4 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974421; called by muse, varscan2
- GABRA4 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51935500; called by muse, varscan2
- GABRB1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs765452965, COSV54972568; called by muse, mutect2, varscan2
- GALNT7 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.519); catalogued as COSV53931402; called by muse, varscan2
- GAS7 | c.815G>A p.G272E (on ENST00000432992 / NM_201433.2; = p.G132E on NM_003644.3) | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100096418; called by muse, mutect2, varscan2
- GCN1 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100325312; called by muse, mutect2, varscan2
- GEMIN4 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100021521; called by muse, mutect2, varscan2
- GEMIN5 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99594175; called by muse, varscan2
- GIGYF1 | c.2879A>T p.E960V | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99309756; called by muse, mutect2, varscan2
- GIMAP8 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as COSV56232130, COSV56233053; called by muse, mutect2, varscan2
- GLP1R | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs1249883851, COSV100952684; called by muse, mutect2, varscan2
- GLRA3 | c.1202A>G p.K401R | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV56872248, COSV99078846; called by muse, varscan2
- GLT6D1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65628455; called by muse, mutect2, varscan2
- GORAB | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.3); catalogued as COSV100883856; called by muse, mutect2, varscan2
- GP1BA | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV56700785; called by muse, mutect2, varscan2
- GPC4 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 136/182 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252511131, COSV100895562; called by muse, mutect2, varscan2
- GPR158 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199592333, COSV100893624, COSV66276134; called by muse, mutect2, varscan2
- GPR158 | c.2672C>T p.T891I | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66278786; called by muse, mutect2, varscan2
- GPR4 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 31/60 reads (52%) | catalogued as COSV100547161; called by muse, mutect2, varscan2
- GPR52 | c.308A>T p.H103L | Missense Mutation (SNP) | VAF 222/472 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99272733; called by muse, mutect2, varscan2
- GPR63 | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.492); catalogued as COSV100013503; called by muse, mutect2, varscan2
- GPRC5B | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs760177081, COSV100315232; called by muse, mutect2, varscan2
- GRAMD2B | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV99587205; called by muse, mutect2, varscan2
- GRID1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs779659096, COSV60037930; called by muse, mutect2, varscan2
- GRIN2A | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771688818, COSV58023816; called by mutect2, varscan2
- GRIN2B | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs867779077, COSV74206078; called by muse, mutect2, varscan2
- GRK5 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 173/493 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV100963171; called by muse, mutect2, varscan2
- GRM1 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as COSV51152723, COSV99268008; called by muse, mutect2, varscan2
- GRM5 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as COSV59596804; called by muse, mutect2, varscan2
- GRM7 | c.522C>T p.I174= | Splice Region (SNP) | VAF 105/173 reads (61%) | catalogued as COSV63137971; called by muse, mutect2, varscan2
- GSPT2 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100468276; called by muse, mutect2, varscan2
- GSTA2 | c.316A>C p.I106L | Missense Mutation (SNP) | VAF 168/368 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV101534066; called by muse, mutect2
- GTF3C3 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99826863; called by muse, mutect2, varscan2
- H1-7 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759956909, COSV58602722; called by muse, mutect2, varscan2
- H2BC21 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.21); catalogued as COSV100480069; called by muse, mutect2, varscan2
- H2BC4 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 134/598 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100020014; called by muse, mutect2, varscan2
- H2BC9 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55099941, COSV99769189; called by muse, mutect2, varscan2
- H2BC9 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1319613952, COSV99769190; called by muse, mutect2, varscan2
- H3C2 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV52520353; called by muse, mutect2, varscan2
- H6PD | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as COSV101072510, COSV66230839; called by muse, mutect2, varscan2
- HACD1 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV100778504; called by muse, mutect2, varscan2
- HACE1 | c.1441T>A p.C481S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV99494102; called by muse, mutect2, varscan2
- HBS1L | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 61/124 reads (49%) | catalogued as COSV100892648; called by muse, mutect2, varscan2
- HDAC10 | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs756987194, COSV99299545; called by muse, mutect2
- HDAC10 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV99299358; called by muse, mutect2
- HDAC6 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100491122; called by muse, mutect2, varscan2
- HEATR6 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99482503; called by muse, mutect2, varscan2
- HELB | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as rs757111101, COSV99922093; called by muse, mutect2, varscan2
- HENMT1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100898677; called by muse, mutect2, varscan2
- HERC1 | c.8015C>T p.S2672F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.624); catalogued as COSV101496765; called by muse, varscan2
- HERC1 | c.7907C>G p.T2636S | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.97); catalogued as rs754461598, COSV101496766; called by muse, varscan2
- HERC5 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99988009; called by muse, mutect2, varscan2
- HEXIM1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100203547; called by muse, mutect2, varscan2
- HFM1 | c.1847T>C p.L616S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646479; called by muse, mutect2, varscan2
- HLA-A | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs41543413, COSV65144602; called by muse, mutect2, varscan2
- HMCN1 | c.13655G>A p.R4552K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV104376449, COSV54942974; called by muse, mutect2, varscan2
- HMGCS2 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557994090, COSV101024869; called by muse, mutect2, varscan2
- HNMT | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV99698597; called by muse, mutect2, varscan2
- HNRNPA1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99267772; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as COSV100079754; called by muse, mutect2, varscan2
- HOGA1 | c.734T>A p.V245D | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101035557; called by muse, mutect2, varscan2
- HOXC4 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1447571758, COSV57700371; called by muse, mutect2, varscan2
- HPSE2 | c.700A>C p.N234H | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.078); catalogued as COSV100986049; called by muse, mutect2, varscan2
- HPSE2 | c.699T>A p.N233K | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as COSV100986051; called by muse, mutect2, varscan2
- HPX | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99793449; called by muse, mutect2, varscan2
- HR | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV100455955, COSV57195129; called by muse, mutect2, varscan2
- HSD11B1 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766626519, COSV99808282; called by muse, mutect2, varscan2
- HSPG2 | c.6127C>A p.L2043I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV101020954; called by muse, mutect2, varscan2
- HSPG2 | c.4793A>G p.Y1598C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV101020959; called by muse, mutect2, varscan2
- HSPH1 | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100185071; called by muse, mutect2, varscan2
- HTR4 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100089081; called by muse, mutect2, varscan2
- HTT | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100751064; called by muse, mutect2, varscan2
- HYDIN | c.7361C>T p.A2454V | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV99993353; called by muse, mutect2, varscan2
- HYOU1 | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101345642; called by muse, mutect2, varscan2
- ICE1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 122/228 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs376008194; called by muse, mutect2, varscan2
- IDO2 | c.484G>A p.E162K (on ENST00000389060; = p.E175K on NM_194294.2) | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs560180578, COSV100584901; called by muse, mutect2, varscan2
- IFI30 | c.745T>C p.F249L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV101325390; called by muse, mutect2, varscan2
- IFI6 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100191537; called by muse, mutect2, varscan2
- IFTAP | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs752758339, COSV57556412; called by muse, mutect2, varscan2
- IGDCC3 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60077780; called by muse, mutect2, varscan2
- IGDCC4 | c.564-1G>A p.X188_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as rs868202699, COSV100733053; called by muse, mutect2
- IGF2BP3 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV99325650; called by muse, mutect2, varscan2
- IGHD | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV101162983; called by muse, mutect2, varscan2
- IGHV2-5 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 108/196 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs1475304387; called by muse, mutect2, varscan2
- IGLV3-9 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.397); catalogued as rs187387271; called by muse, mutect2, varscan2
- IGSF10 | c.6902G>A p.R2301K | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99187371; called by muse, mutect2
- IGSF21 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99245740; called by muse, mutect2, varscan2
- IGSF21 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 104/491 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52127135; called by muse, varscan2
- IGSF9B | c.3926G>A p.R1309K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as COSV100318160; called by muse, mutect2, varscan2
- IHH | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99838575; called by muse, mutect2, varscan2
- IL36A | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52084110; called by muse, varscan2
- ILRUN | c.605C>T p.P202L (on ENST00000374023 / NM_024294.4; = p.P136L on NM_022758.6) | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs765996037, COSV100927278; called by muse, mutect2, varscan2
- IMPA2 | c.836C>G p.T279R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.261); catalogued as COSV99302695; called by muse, mutect2, varscan2
- INPP1 | c.256A>T p.N86Y | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100487291; called by muse, mutect2, varscan2
- INTS5 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV100399736, COSV100399747; called by muse, mutect2, varscan2
- IQCH | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100246205, COSV60049357; called by muse, mutect2, varscan2
- IQCH | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100246208; called by muse, mutect2, varscan2
- IQCH | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 255/694 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs769295973, COSV60061030; called by muse, mutect2, varscan2
- IQSEC3 | c.1832C>T p.S611L (on ENST00000538872 / NM_001170738.2; = p.S308L on NM_015232.1) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs376678794; called by muse, mutect2
- IQUB | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61243173; called by muse, mutect2, varscan2
- IRF6 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 287/675 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100884009; called by muse, mutect2, varscan2
- IRX6 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99306678; called by muse, mutect2, varscan2
- ITGAD | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV101210515, COSV101210539; called by mutect2, varscan2
- ITGB1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100171873; called by muse, mutect2, varscan2
- ITGB3 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101457649, COSV71384183; called by muse, mutect2, varscan2
- ITGB3 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV101457650; called by muse, mutect2, varscan2
- ITIH2 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100623352; called by muse, mutect2, varscan2
- ITPR1 | c.6227C>T p.P2076L (on ENST00000354582; = p.P2021L on NM_002222.7) | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57010555; called by muse, mutect2, varscan2
- ITPRID1 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV100087121; called by muse, mutect2, varscan2
- JAK2 | c.1449G>A p.M483I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs767808355, COSV101077343; called by muse, mutect2, varscan2
- JAKMIP2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54605171; called by muse, mutect2, varscan2
- JUP | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60277750; called by muse, mutect2, varscan2
- KALRN | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs267599582, COSV99566295; called by muse, mutect2, varscan2
- KANK4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.134); catalogued as rs868518757, COSV62986804; called by muse, mutect2, varscan2
- KATNAL1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV101017096; called by muse, mutect2, varscan2
- KATNIP | c.3758G>T p.R1253I | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99851663; called by muse, mutect2, varscan2
- KCNA10 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs773796325, COSV100871465; called by muse, mutect2, varscan2
- KCNA4 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 132/434 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60250901, COSV60253545; called by muse, mutect2, varscan2
- KCNAB1 | c.1124G>A p.G375E (on ENST00000490337 / NM_172160.3; = p.G364E on NM_003471.3) | Missense Mutation (SNP) | VAF 1254/1995 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100204709; called by muse, mutect2, varscan2
- KCNB2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.96); catalogued as COSV73049036; called by muse, mutect2, varscan2
- KCNC3 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1256051209, COSV65387173; called by muse, mutect2, varscan2
- KCND1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV99502079; called by muse, mutect2, varscan2
- KCNH7 | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs370772173, COSV100147559; called by muse, mutect2, varscan2
- KCNIP1 | c.626C>T p.S209L (on ENST00000411494 / NM_001034837.3; = p.S198L on NM_014592.4) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100199889; called by muse, mutect2, varscan2
- KCNJ1 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131422; called by muse, mutect2, varscan2
- KCNJ11 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV60595908; called by muse, mutect2, varscan2
- KCNJ8 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 105/184 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.253); catalogued as COSV53715759, COSV53717400, COSV99557671; called by muse, mutect2, varscan2
- KCNK10 | c.1565A>G p.D522G | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100068940; called by muse, mutect2, varscan2
- KCNK10 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 154/357 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs371294105, COSV56639118; called by muse, mutect2, varscan2
- KCNK9 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100271438; called by muse, mutect2, varscan2
- KCNN2 | c.334A>C p.K112Q (on ENST00000264773; = p.K324Q on NM_021614.4) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV99300347; called by muse, mutect2, varscan2
- KDR | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 155/382 reads (41%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.935); catalogued as COSV99818295; called by muse, mutect2, varscan2
- KIAA0895 | c.1552G>A p.D518N (on ENST00000297063 / NM_001100425.2; = p.D467N on NM_015314.3) | Missense Mutation (SNP) | VAF 116/345 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99767055; called by muse, mutect2, varscan2
- KIAA1109 | c.9131C>T p.S3044F | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV52662409; called by muse, mutect2, varscan2
- KIAA1549L | c.17C>T p.S6F (on ENST00000321505; = p.S303F on NM_012194.3) | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99684076; called by muse, mutect2, varscan2
- KIAA1549L | c.697G>A p.G233S (on ENST00000321505; = p.G530S on NM_012194.3) | Missense Mutation (SNP) | VAF 104/291 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as rs762346573, COSV99684081; called by muse, mutect2, varscan2
- KIAA2026 | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 120/295 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs754494052, COSV67358375; called by muse, mutect2, varscan2
- KIF13A | c.1550C>T p.T517I | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as rs368788633; called by muse, mutect2, varscan2
- KIF21B | c.4832T>A p.L1611* (on ENST00000422435 / NM_001252100.2; = p.L1598* on NM_017596.4) | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100144877; called by muse, mutect2, varscan2
- KIF21B | c.3551G>A p.R1184Q | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.111); catalogued as rs371053876; called by muse, mutect2
- KIF2A | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV101136594; called by mutect2, varscan2
- KIF4B | c.2562G>A p.W854* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | catalogued as COSV101469364; called by muse, mutect2, varscan2
- KIRREL2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.575); catalogued as COSV99384242; called by muse, mutect2, varscan2
- KIRREL2 | c.1944G>A p.M648I | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99384245; called by muse, mutect2, varscan2
- KIRREL3 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 64/201 reads (32%) | catalogued as COSV101375214; called by muse, mutect2, varscan2
- KLF12 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1302584442, COSV100888577; called by muse, mutect2, varscan2
- KLF12 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 128/249 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100888578; called by muse, mutect2, varscan2
- KLF9 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009605; called by muse, mutect2, varscan2
- KLHL1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64783010, COSV64787166; called by muse, mutect2, varscan2
- KLHL22 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as COSV100186171; called by muse, mutect2, varscan2
- KMT2D | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs371286331; called by muse, mutect2, varscan2
- KNL1 | c.2162T>G p.L721W (on ENST00000346991 / NM_170589.5; = p.L695W on NM_144508.5) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100706790; called by muse, mutect2, varscan2
- KNTC1 | c.6035C>T p.P2012L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100338588; called by muse, mutect2, varscan2
- KRT24 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 102/586 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52881575, COSV99232114; called by muse, mutect2, varscan2
- KRT27 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1330892040, COSV100053325; called by muse, mutect2, varscan2
- KRT73 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs993341388, COSV59838270; called by muse, mutect2, varscan2
- KRT73 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV99988699; called by muse, mutect2, varscan2
- KRT83 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 75/395 reads (19%) | catalogued as COSV99531349; called by muse, mutect2, varscan2
- KRT85 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 70/179 reads (39%) | catalogued as COSV99225625; called by muse, mutect2, varscan2
- LAMA4 | c.4999G>A p.G1667R (on ENST00000230538 / NM_001105206.3; = p.G1660R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100039004, COSV57906008; called by muse, mutect2, varscan2
- LAMP3 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 106/703 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.089); catalogued as rs1179848856, COSV99660689; called by muse, mutect2, varscan2
- LAMP5 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV55717004, COSV99855551; called by muse, mutect2, varscan2
- LARP1 | c.1519C>T p.P507S (on ENST00000518297 / NM_033551.3; = p.P430S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100303966; called by muse, mutect2, varscan2
- LARP1 | c.1520C>T p.P507L (on ENST00000518297 / NM_033551.3; = p.P430L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100303968; called by muse, mutect2, varscan2
- LAYN | c.941C>T p.S314L (on ENST00000375615 / NM_001258390.1; = p.S306L on NM_178834.5) | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866324427, COSV65105735; called by muse, mutect2, varscan2
- LCK | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV60740872; called by muse, mutect2, varscan2
- LCT | c.3109G>T p.A1037S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752288117, COSV99930068; called by muse, mutect2, varscan2
- LCTL | c.705+1G>A p.X235_splice | Splice Site (SNP) | VAF 28/83 reads (34%) | catalogued as rs1165454536, COSV100427275; called by muse, mutect2, varscan2
- LEPR | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as COSV100756711; called by muse, mutect2
- LGR5 | c.2714C>T p.P905L | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1292453188, COSV99878225; called by muse, mutect2, varscan2
- LHX4 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99761760; called by muse, mutect2, varscan2
- LIFR | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 52/112 reads (46%) | catalogued as COSV99664964; called by muse, mutect2, varscan2
- LIG4 | c.2644T>A p.F882I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100800007; called by muse, mutect2, varscan2
- LILRB5 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 223/335 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs755997832, COSV60256644, COSV60259897; called by muse, mutect2, varscan2
- LIMK2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100058791; called by muse, mutect2, varscan2
- LIMS1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 55/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773956158, COSV100185961, COSV57540435; called by muse, mutect2
- LIMS1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs761280581, COSV100185967; called by muse, mutect2
- LINC02210-CRHR1 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99523946; called by muse, mutect2, varscan2
- LINGO4 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.052); catalogued as rs868651643, COSV59091159; called by muse, mutect2, varscan2
- LITAF | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV100243098, COSV100243206; called by muse, mutect2, varscan2
- LPP | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 241/1802 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs757883563, COSV100446226, COSV100447957; called by muse, mutect2, varscan2
- LRP1B | c.7327C>T p.R2443C | Missense Mutation (SNP) | VAF 86/355 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774430605, COSV67190954; called by muse, mutect2, varscan2
- LRP1B | c.6218G>C p.G2073A | Missense Mutation (SNP) | VAF 117/346 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101258938, COSV67254270; called by muse, mutect2, varscan2
- LRP8 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100036772; called by muse, mutect2, varscan2
- LRP8 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV100036775; called by muse, mutect2, varscan2
- LRPPRC | c.4111C>T p.P1371S | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1173633095, COSV53234393; called by muse, varscan2
- LRRC30 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 74/262 reads (28%) | catalogued as COSV67302362; called by muse, mutect2, varscan2
- LRRC32 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs766920653, COSV99477145; called by muse, mutect2, varscan2
- LRRC40 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs760500758, COSV63942461; called by muse, mutect2, varscan2
- LRRFIP2 | c.1445G>A p.W482* | Nonsense Mutation (SNP) | VAF 53/97 reads (55%) | catalogued as COSV100368617; called by muse, mutect2, varscan2
- LRRIQ3 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs202037480, COSV63041614, COSV99063517; called by muse, mutect2, varscan2
- MACROD2 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV53987801, COSV99439032; called by muse, mutect2, varscan2
- MAGEB6 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 95/119 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV66873007; called by muse, mutect2, varscan2
- MAGI2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100835678; called by muse, varscan2
- MAJIN | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100104574; called by muse, mutect2, varscan2
- MAOB | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 32/37 reads (86%) | catalogued as COSV100956177; called by muse, mutect2, varscan2
- MAOB | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 33/38 reads (87%) | catalogued as COSV100956179; called by muse, mutect2, varscan2
- MAP1B | c.5323G>A p.G1775R | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV99702748; called by muse, mutect2, varscan2
- MAP3K7CL | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 72/110 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs754159000, COSV99726796; called by muse, mutect2, varscan2
- MAPK15 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100568036; called by muse, mutect2, varscan2
- MAPK8IP1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53797785; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1850G>A p.G617D | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53799343, COSV99571647; called by muse, mutect2, varscan2
- MASP1 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 411/617 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99397508; called by muse, mutect2, varscan2
- MAST3 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99445943; called by muse, mutect2, varscan2
- MAST4 | c.6815C>A p.S2272Y (on ENST00000403625 / NM_001164664.2; = p.S2083Y on NM_015183.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.381); catalogued as COSV99845171; called by muse, mutect2, varscan2
- MBD5 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs866370990, COSV68697354; called by muse, mutect2, varscan2
- MBL2 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100906380; called by muse, varscan2
- MBL2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as COSV64758154; called by muse, varscan2
- MCMBP | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100750141; called by muse, mutect2, varscan2
- MCTP1 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100387767; called by muse, mutect2, varscan2
- MDC1 | c.4264C>T p.Q1422* | Nonsense Mutation (SNP) | VAF 82/249 reads (33%) | catalogued as COSV100903005; called by muse, mutect2, varscan2
- ME3 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 195/571 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100042437; called by muse, mutect2, varscan2
- MECOM | c.767C>T p.S256L (on ENST00000468789 / NM_001105078.4; = p.S444L on NM_004991.4) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV52964071; called by muse, mutect2, varscan2
- MED24 | c.213G>A p.Q71= | Splice Region (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100673309; called by muse, mutect2, varscan2
- MERTK | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 112/399 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.444); catalogued as COSV54926861; called by muse, mutect2, varscan2
- MFGE8 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 176/472 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183973; called by muse, mutect2, varscan2
- MGAM | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554464349, COSV72076058; called by muse, mutect2, varscan2
- MGAM | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.211); catalogued as COSV101527610, COSV72075458; called by muse, mutect2, varscan2
- MGAM | c.3726G>A p.W1242* | Nonsense Mutation (SNP) | VAF 135/605 reads (22%) | catalogued as COSV72075636; called by muse, mutect2, varscan2
- MGAT4C | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59834924; called by muse, mutect2, varscan2
- MGAT4C | c.974T>A p.L325Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153191; called by muse, mutect2, varscan2
- MGAT4C | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV59830995; called by muse, varscan2
- MIA3 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV100719512; called by muse, mutect2, varscan2
- MIB1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 61/204 reads (30%) | catalogued as rs1317522131, COSV55087426; called by mutect2, varscan2
- MICAL1 | c.3184G>A p.G1062R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV99238083; called by muse, mutect2, varscan2
- MINAR1 | c.2436C>A p.Y812* | Nonsense Mutation (SNP) | VAF 48/151 reads (32%) | catalogued as COSV100549094; called by muse, mutect2, varscan2
- MINDY1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100385537; called by muse, mutect2, varscan2
- MINK1 | c.2467T>C p.Y823H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99545190; called by muse, mutect2, varscan2
- MKLN1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.331); catalogued as COSV100759943; called by muse, mutect2, varscan2
- MKX | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.122); catalogued as COSV65391846; called by muse, mutect2, varscan2
- MLC1 | c.1104G>A p.W368* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100286481; called by muse, mutect2, varscan2
- MLH1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as COSV51614229; called by muse, mutect2
- MMEL1 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99984203; called by muse, mutect2, varscan2
- MMP19 | c.296T>G p.L99R | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100491215; called by muse, varscan2
- MMP19 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100491220; called by muse, varscan2
- MMP27 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99498588; called by muse, mutect2
- MMP7 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99497127; called by muse, mutect2, varscan2
- MOV10 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV100659697; called by muse, mutect2, varscan2
- MOV10L1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV99434593; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3115C>T p.P1039S | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV100186997; called by muse, mutect2, varscan2
- MPO | c.1904G>A p.G635D | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51861822, COSV99229160; called by muse, mutect2, varscan2
- MRI1 | c.1018G>A p.E340K (on ENST00000040663 / NM_001031727.4; = p.E293K on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99237664; called by muse, mutect2, varscan2
- MRM3 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100444403; called by muse, varscan2
- MROH5 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); catalogued as COSV101436083; called by muse, mutect2, varscan2
- MROH7 | c.3927G>A p.W1309* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as rs756224709, COSV100988611; called by muse, mutect2, varscan2
- MRPL4 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV99460208; called by muse, mutect2, varscan2
- MRTFA | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 236/956 reads (25%) | catalogued as COSV100844265; called by muse, mutect2, varscan2
- MSANTD2 | c.1101C>A p.N367K (on ENST00000374979 / NM_001308027.2; = p.N315K on NM_024631.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.994); catalogued as COSV99515835; called by muse, mutect2, varscan2
- MSI1 | c.856A>T p.T286S | Missense Mutation (SNP) | VAF 130/272 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99981644; called by muse, mutect2, varscan2
- MSRB3 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV57588817, COSV57590174; called by muse, mutect2, varscan2
- MSX2 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53327647, COSV99496933; called by muse, mutect2, varscan2
- MTF1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 81/414 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV100888684; called by muse, mutect2, varscan2
- MTMR2 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 84/271 reads (31%) | catalogued as rs1283810204, COSV60582004; called by muse, mutect2, varscan2
- MUC16 | c.35599C>T p.L11867F | Missense Mutation (SNP) | VAF 178/798 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV67470654; called by muse, mutect2, varscan2
- MUC16 | c.23174C>T p.P7725L | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs566528880, COSV101198080, COSV67450285, COSV67480183; called by muse, mutect2, varscan2
- MUC16 | c.21946C>T p.P7316S | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.094); catalogued as rs1178926864, COSV101200631; called by muse, mutect2, varscan2
- MUC17 | c.2477T>A p.L826H | Missense Mutation (SNP) | VAF 152/749 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.523); catalogued as COSV100074411; called by muse, mutect2, varscan2
- MUC17 | c.7681G>T p.G2561C | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV100074413; called by muse, mutect2, varscan2
- MX1 | c.491T>G p.L164R | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367753635; called by muse, mutect2, varscan2
- MYBPC1 | c.1564C>T p.P522S (on ENST00000550270 / NM_206820.2; = p.P547S on NM_002465.4) | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100638190; called by muse, mutect2, varscan2
- MYCBPAP | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.482); catalogued as COSV100088660; called by muse, mutect2, varscan2
- MYCT1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1031652406, COSV100924082, COSV65891240; called by muse, mutect2, varscan2
- MYH4 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 100/181 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55116787; called by muse, mutect2, varscan2
- MYH6 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1297856283, COSV62451594; called by muse, mutect2, varscan2
- MYLK2 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65659843; called by muse, mutect2, varscan2
- MYLK3 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.073); catalogued as COSV101189167; called by muse, mutect2, varscan2
- MYO15A | c.6889C>T p.P2297S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99233800; called by mutect2, varscan2
- MYO15A | c.10448G>A p.G3483E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007276558, COSV52755973, COSV99233263; called by muse, mutect2, varscan2
- MYO16 | c.3972A>T p.E1324D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100696983; called by muse, mutect2, varscan2
- MYO18B | c.6934G>A p.E2312K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV59136218; called by muse, mutect2, varscan2
- MYO1F | c.1182+1G>A p.X394_splice | Splice Site (SNP) | VAF 26/85 reads (31%) | catalogued as COSV100596921; called by muse, mutect2, varscan2
- MYO1F | c.1182G>A p.Q394= | Splice Region (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100596922; called by muse, mutect2, varscan2
- MYO3A | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV99780808; called by muse, mutect2, varscan2
- MYO5C | c.5098G>A p.D1700N | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99953542; called by muse, mutect2, varscan2
- MYO7B | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67347318; called by muse, mutect2, varscan2
- MYOF | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1482116305, COSV100826012; called by muse, mutect2
- MYT1L | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV67710462; called by muse, mutect2, varscan2
- NAALADL1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761030005, COSV100368185; called by muse, mutect2, varscan2
- NAALADL2 | c.2290G>C p.E764Q | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV101495433, COSV71984238; called by muse, mutect2
- NALCN | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99216742; called by muse, mutect2, varscan2
- NAV2 | c.3406C>T p.P1136S (on ENST00000396087 / NM_001244963.2; = p.P1113S on NM_145117.5) | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs752654996, COSV100217424; called by muse, mutect2, varscan2
- NAV3 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 124/678 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV99893843; called by muse, mutect2, varscan2
- NBEA | c.4852C>T p.P1618S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV100082657; called by muse, mutect2, varscan2
- NBEA | c.8644G>A p.D2882N | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.671); catalogued as COSV100082659; called by muse, mutect2, varscan2
- NCAM1 | c.1778G>A p.G593E (on ENST00000316851 / NM_181351.5; = p.G583E on NM_000615.7) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100378249; called by muse, mutect2, varscan2
- NCK1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 35/178 reads (20%) | catalogued as COSV56637012, COSV99999376; called by muse, mutect2, varscan2
- NCKAP5L | c.2132C>T p.S711F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100259056; called by muse, mutect2
- NDST2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV100014231; called by muse, mutect2, varscan2
- NDST3 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV99631354; called by muse, mutect2, varscan2
- NECTIN1 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 71/228 reads (31%) | catalogued as COSV99872479; called by muse, mutect2, varscan2
- NEIL3 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV99220787; called by muse, mutect2, varscan2
- NEK9 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1169016166, COSV99464367; called by muse, mutect2, varscan2
- NELL1 | c.2158-1G>A p.X720_splice | Splice Site (SNP) | VAF 38/171 reads (22%) | catalogued as COSV100123441; called by muse, mutect2, varscan2
- NEMF | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 37/130 reads (28%) | catalogued as COSV100027927; called by muse, mutect2, varscan2
- NEURL4 | c.4502C>T p.S1501F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100223169; called by mutect2, varscan2
- NEURL4 | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100223171; called by muse, mutect2, varscan2
- NEXMIF | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 197/271 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766391935, COSV50083099; called by muse, mutect2, varscan2
- NFAM1 | c.600G>T p.R200S | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV100216012, COSV61194884; called by muse, mutect2, varscan2
- NFE2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 136/318 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56455364; called by muse, mutect2, varscan2
- NFXL1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV101040552; called by muse, mutect2, varscan2
- NGEF | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99890188; called by muse, mutect2, varscan2
- NIBAN3 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs888799687, COSV99962577; called by muse, mutect2, varscan2
- NIF3L1 | c.106T>A p.S36T (on ENST00000409020 / NM_001369444.1; = p.S9T on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.048); catalogued as COSV99626919; called by muse, mutect2, varscan2
- NIT1 | c.717G>A p.E239= | Splice Region (SNP) | VAF 95/205 reads (46%) | catalogued as COSV100919119; called by muse, mutect2, varscan2
- NLGN3 | c.2057C>T p.S686F (on ENST00000358741 / NM_181303.2; = p.S666F on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs778187276, COSV100704940; called by muse, mutect2, varscan2
- NLRC4 | c.2042G>A p.G681E | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs762826149, COSV100707475; called by muse, mutect2, varscan2
- NLRP3 | c.100A>T p.K34* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100276432; called by muse, mutect2, varscan2
- NLRP8 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 270/431 reads (63%) | catalogued as COSV99405711; called by muse, mutect2, varscan2
- NLRP9 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60460431; called by muse, mutect2, varscan2
- NLRP9 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 88/131 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV60467376; called by muse, mutect2, varscan2
- NOA1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436780263; called by mutect2, varscan2
- NPAS2 | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1472754553, COSV59556835; called by muse, mutect2, varscan2
- NPEPL1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs370807734; called by muse, mutect2, varscan2
- NRAP | c.4718G>A p.R1573K (on ENST00000359988 / NM_001322945.2; = p.R1538K on NM_006175.4) | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100668043; called by muse, mutect2, varscan2
- NRN1L | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV59303573; called by mutect2, varscan2
- NRROS | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as COSV100145561; called by muse, mutect2, varscan2
- NRXN1 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101278638; called by muse, mutect2, varscan2
- NRXN2 | c.3427A>C p.K1143Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99635194; called by muse, mutect2, varscan2
- NRXN3 | c.2360G>C p.S787T (on ENST00000335750 / NM_001330195.2; = p.S414T on NM_004796.6) | Missense Mutation (SNP) | VAF 238/473 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100206890; called by muse, mutect2, varscan2
- NT5C2 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100583639; called by muse, mutect2, varscan2
- NT5M | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV101198631; called by muse, mutect2, varscan2
- NTRK2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 112/232 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs752393508, COSV52862947, COSV52868949; called by muse, mutect2, varscan2
- NUDCD2 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV57085866; called by muse, mutect2
1,309 further variants in this file (562 protein-altering or splice-affecting, 699 silent, 48 other) are not listed here.
